Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5194, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5194-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

TCGA - BP - 5194

Specimens Submitted:

1: SP: Kidney, right mass; partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right mass; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.5 cm

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh and is labeled "right renal tumor". It consists of a 5.0 x 4.0 x 3.8 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal an orange yellow mass with hemorrhage and necrosis which measures 3.5 x 3.0 x 3.0 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

RS - representative sections

Summary of Sections:

Part 1: SP; Kidney, right mass; partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	rs	1
5	t	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP; RIGHT RENAL TUMOR (REDACTED): CLEAR CELL CARCINOMA, NEGATIVE MARGIN (REDACTED)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 34e49c79-7c32-4c2c-a1ff-d5961a6817b4 (TCGA-BP-5194.7D2B2F32-1828-41C8-8B17-1C017C527FCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).